Surgical pathology report (de-identified scan), TCGA case TCGA-29-1693, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1693-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

Surg Path

CLINICAL HISTORY:
Not provided.

TCGA-29-1693

GROSS EXAMINATION:

- A. "Omentum (AF1)", received fresh for frozen section is a 20 x 6 x 2 cm portion of omentum with numerous firm papillary tumor nodules up to 4 cm in diameter (frozen section AF1 remnant), additional in block A2.
- B. "Left thigh lipoma, short stitch superior, long-lateral", received unfixed is an 11 x 7 x 4 cm mass comprised primarily of well defined lobules of adipose tissue. The specimen is marked with blue ink and representative sections are submitted in block B1.
- C. "Right tube and ovary", received unfixed is a 2 x 1 x cm ovary and attached 3.5 x 0.5 cm fallopian tube. A tiny focus of papillary material is present focally on the ovarian surface (C1).
- D. "Left ovarian mass", received unfixed is a 3 x 2 x 0.6 cm solid tumor composed of moderately firm white tissue (D1).
- E. "Left ovary", received unfixed is a 58 gram, 6.5 x 6 x 2.5 cm specimen consisting of a complex multicystic mass with extensive areas of solid tumor formation and focal necrosis (E1-E3). No definitive ovarian or fallopian tube remnant are identified.
- F. "Omentum", received unfixed is a 6 x 3 x 1.0 cm fragment of omentum with a single lesion 0.5 cm area suspicious for tumor (F1).
- G. "Left pelvic side wall", received unfixed is a 3 x 3 x 1 cm fragment of adipose tissue with embedded and adherent firm white tissue (G1).
- H. "Sigmoid colon", received unfixed is an unoriented segment of large bowel 12 cm in length that is stapled at both ends. The serosal surface is hemorrhagic and there is extensive deposits of tumor in several foci extending from the serosal surface and into the wall of the colon. The opened specimen reveals a single focus of transmural tumor invasion with extensive underlining of the mucosa and numerous tumor nodules in the pericolonic adipose tissue (H1-H2:largest lesion, H3: additional lesion). The mucosal margin of resection appears grossly free of tumor (H4-H5).
- I. "Right pelvic side wall", received unfixed is a 2 x 2 x 1 cm aggregate of multiple fragments of irregular tan and brown tissue which are submitted in toto in block I1.
- J. "Transverse colon nodule", received unfixed is a firm white nodule 2 x 1 x 1 cm in size with a small amount of surrounding adipose tissue (J1).
- K. "Left pelvic side wall", received unfixed are several fragments of hemorrhagic firm white tissue measuring 2 x 2 x 1 cm in aggregate which are submitted in toto in block K1.

[REDACTED]

INTRA OPERATIVE CONSULTATION:

- A. "Omentum":
AF1- papillary serous carcinoma. Favor ovarian primary [REDACTED]

DIAGNOSIS:

[REDACTED]

[page 2 of 2]
- E. LEFT OVARY (58 GM, 6.5 CM) AND (D) LEFT OVARIAN MASS (3 CM).
SEROUS ADENOCARCINOMA, FIGO GRADE 3,
WITH EXTENSIVE METASTASES/IMPLANTS AND LYMPHOVASCULAR SPREAD TO:
A. OMENTUM.
F. OMENTUM.
G. LEFT PELVIC SIDEWALL.
H. SIGMOID COLON: ONE LATERAL RESECTION MARGIN IS POSITIVE.
I. RIGHT PELVIC SIDEWALL.
J. TRANSVERSE COLON NODULE.
K. LEFT PELVIC SIDEWALL.

TCGA-29-1693

THE FOLLOWING SPECIMENS ARE FREE OF TUMOR:

- B. LEFT THIGH LIPOMA.
C. RIGHT OVARY AND FALLOPIAN TUBE.
E. LEFT FALLOPIAN TUBE.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 6ea2e75a-f166-4e10-b473-158bf2300eac (TCGA-29-1693.90087244-634D-45EB-A877-FF7CC6BD2282.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).